TARGET case TARGET-00-RO02379 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/0be0de3d-b6e0-4279-a3af-f2eef653452a

Biospecimens (1 sample)
- Sample TARGET-00-RO02379-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
